Somatic mutation profile of tumor specimen C3L-05601-04 (aliquot CPT0412620006) from CPTAC case C3L-05601, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.6 years (27,616 days).
Specimen C3L-05601-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47252d30-9ba9-4ffa-8c12-bcf768f78971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05601-31 (Blood Derived Normal), aliquot CPT0412740004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a7b7b29-8ee9-4f6b-968d-535e6dbdd556

The open-access MAF lists 113 somatic variants for this specimen: 80 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 31, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 1, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 75/417 reads (18%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 98/307 reads (32%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3353G>A p.R1118H (on ENST00000404938 / NM_001163941.2; = p.R673H on NM_178559.6) | Missense Mutation (SNP) | VAF 62/435 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs747248780; called by muse, mutect2, varscan2
- ADAMTS13 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 92/464 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1554786791; called by muse, mutect2, varscan2
- CACNG8 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1262935348; called by muse, mutect2
- CD200 | c.569G>A p.R190H (on ENST00000473539 / NM_001004196.3; = p.R165H on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs759307241, COSV59862577; called by muse, mutect2
- CSMD2 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs764236355, COSV53949729; called by muse, mutect2, varscan2
- CTNNBL1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 52/500 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260556734, COSV63745254; called by muse, varscan2
- DAB2IP | c.755A>T p.D252V (on ENST00000408936; = p.D224V on NM_032552.3) | Missense Mutation (SNP) | VAF 72/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99405529; called by muse, mutect2, varscan2
- EFHC2 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.211); catalogued as rs776581328; called by muse, mutect2, varscan2
- ELFN1 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 29/644 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1206191418; called by muse, mutect2
- F5 | c.2985G>C p.Q995H | Missense Mutation (SNP) | VAF 32/582 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV63125689; called by muse, mutect2
- FNDC1 | c.2920C>T p.R974C | Missense Mutation (SNP) | VAF 31/470 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1371359713, COSV51946447; called by muse, mutect2
- GALNT17 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs746690136, COSV61178305; called by muse, mutect2, varscan2
- KCTD9 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV99648446; called by muse, mutect2
- KHDRBS3 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63421444; called by muse, varscan2
- KRTAP4-4 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 113/1728 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs943933243, COSV66811633; called by muse, mutect2
- NOS1AP | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 166/412 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as rs746991588, COSV100722744, COSV100722837; called by muse, varscan2
- PCDH17 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 43/596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64973017; called by muse, mutect2
- PDLIM2 | c.475G>T p.A159S (on ENST00000397760; = p.A409S on NM_021630.6) | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1177778217; called by muse, mutect2, varscan2
- PLCG1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs770679029, COSV54824611; called by muse, mutect2
- RP1L1 | c.2917T>C p.Y973H | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.199); catalogued as rs908038796; called by muse, mutect2
- SATB1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 52/349 reads (15%) | catalogued as COSV58668666; called by muse, mutect2, varscan2
- SCART1 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 99/427 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1279128791; called by muse, mutect2, varscan2
- SEMA3E | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.969); catalogued as rs752160300, COSV100316908, COSV57078209; called by muse, mutect2, varscan2
- SH2D3C | c.2057C>T p.A686V (on ENST00000314830 / NM_170600.3; = p.A529V on NM_005489.4) | Missense Mutation (SNP) | VAF 72/379 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1293443058; called by muse, mutect2, varscan2
- TAF6L | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 41/456 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs138817605; called by muse, mutect2
- TCERG1 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1047211226, COSV99695102; called by muse, mutect2
- TENM2 | c.2888G>A p.R963H (on ENST00000518659 / NM_001122679.2; = p.R731H on NM_001080428.3) | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764709973; called by muse, mutect2, varscan2
- TRIM9 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 155/414 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs768445636, COSV100030883; called by muse, mutect2, varscan2
- ULK3 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 34/346 reads (10%) | catalogued as rs1334430400; called by muse, mutect2
- WNK2 | c.4724C>T p.P1575L (on ENST00000297954 / NM_001282394.1; = p.P1538L on NM_006648.3) | Missense Mutation (SNP) | VAF 77/545 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561550244; called by muse, mutect2, varscan2
- ZDBF2 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs184921981, COSV65628783; called by muse, mutect2
- ZDHHC9 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs869312679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZIC4 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67170909; called by muse, varscan2
- AHNAK2 | c.15028G>A p.D5010N | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2
- ALKBH4 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ARHGAP30 | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 14/534 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2
- ARID2 | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ART5 | c.729G>C p.L243F | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.721); called by muse, mutect2
- BICD1 | c.2655del p.D886Ifs*10 | Frame Shift Del (DEL) | VAF 82/381 reads (22%) | called by mutect2, pindel, varscan2
- BPGM | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BPIFA3 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- C12orf40 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1C | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNB2 | c.799A>C p.K267Q (on ENST00000324631 / NM_201596.3; = p.K212Q on NM_000724.4) | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CHL1 | c.3574G>A p.G1192R (on ENST00000397491 / NM_001253387.1; = p.G1208R on NM_006614.4) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- DMAP1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXW9 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); called by muse, mutect2
- FOXK2 | c.1019G>C p.S340T | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FUOM | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 46/489 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.163); called by muse, mutect2
- GJA3 | c.629T>G p.V210G | Missense Mutation (SNP) | VAF 163/506 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGB1 | c.4501del p.S1501Vfs*38 | Frame Shift Del (DEL) | VAF 27/312 reads (9%) | called by mutect2, pindel
- GPR39 | c.440dup p.P149Tfs*29 | Frame Shift Ins (INS) | VAF 96/495 reads (19%) | called by mutect2, pindel, varscan2
- GPRC6A | c.2385G>A p.W795* | Nonsense Mutation (SNP) | VAF 20/348 reads (6%) | called by muse, mutect2
- HEXIM1 | c.637C>G p.H213D | Missense Mutation (SNP) | VAF 14/471 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- HR | c.3043A>C p.S1015R | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- KMT2C | c.6701C>A p.T2234N | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- LAMA1 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAP2K4 | c.176T>G p.F59C | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MCHR1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 78/501 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MRM3 | c.527_529del p.W176del | In Frame Del (DEL) | VAF 21/198 reads (11%) | called by mutect2, pindel
- MYH7 | c.5392G>C p.D1798H | Missense Mutation (SNP) | VAF 69/586 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEO1 | c.3545A>G p.N1182S | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.688); called by muse, mutect2
- NOMO1 | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOP14 | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDH9 | c.2995C>G p.Q999E | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PHACTR3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by mutect2, varscan2
- POLR1G | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- PRSS36 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 112/567 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PTPRT | c.2033C>A p.P678Q | Missense Mutation (SNP) | VAF 55/634 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- RNF133 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SCARF2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2
- TPST1 | c.701G>T p.C234F | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM75P | c.834del p.P279Lfs*11 | Frame Shift Del (DEL) | VAF 16/194 reads (8%) | called by mutect2, pindel
- ZBTB33 | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ZFYVE26 | c.4972A>G p.K1658E | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ZNF221 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF526 | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 26/601 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- ZNF540 | c.1647A>C p.K549N | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2
- ANKRD44 | c.2850G>A p.A950= | Silent (SNP) | VAF 20/334 reads (6%) | catalogued as rs370657568, COSV99984393; called by muse, mutect2
- BAZ1B | c.4089C>T p.P1363= | Silent (SNP) | VAF 53/321 reads (17%) | catalogued as rs535596302; called by muse, mutect2, varscan2
- CHST8 | c.876C>T p.R292= | Silent (SNP) | VAF 20/664 reads (3%) | called by muse, mutect2
- COL27A1 | c.1764G>A p.P588= | Silent (SNP) | VAF 51/600 reads (9%) | catalogued as rs762087400; called by muse, mutect2
- CSMD1 | c.705C>A p.T235= | Silent (SNP) | VAF 36/462 reads (8%) | catalogued as rs372625151; called by muse, mutect2
- DCAF4L2 | c.486G>A p.S162= | Silent (SNP) | VAF 18/553 reads (3%) | catalogued as rs928287261, COSV100151222; called by muse, mutect2
- DTNA | c.1770G>A p.P590= | Silent (SNP) | VAF 60/424 reads (14%) | catalogued as rs756382217, COSV52021001; called by muse, mutect2, varscan2
- EDNRB | c.327C>T p.C109= (on ENST00000377211 / NM_001201397.1; = p.C19= on NM_000115.5) | Silent (SNP) | VAF 89/493 reads (18%) | catalogued as rs768126403; called by muse, mutect2, varscan2
- ERCC4 | c.1620G>A p.S540= | Silent (SNP) | VAF 66/351 reads (19%) | catalogued as rs769817145; called by muse, varscan2
- GABPA | c.489G>A p.V163= | Silent (SNP) | VAF 47/210 reads (22%) | catalogued as rs1239762663; called by muse, mutect2, varscan2
- GALNT16 | c.264G>A p.Q88= | Silent (SNP) | VAF 44/650 reads (7%) | called by muse, mutect2
- IRX3 | c.1371C>G p.P457= | Silent (SNP) | VAF 64/313 reads (20%) | called by muse, mutect2, varscan2
- KAZN | c.1374G>A p.V458= | Silent (SNP) | VAF 13/379 reads (3%) | called by muse, mutect2
- MUC16 | c.16527T>G p.S5509= | Silent (SNP) | VAF 36/428 reads (8%) | catalogued as COSV67446521, COSV67464155; called by muse, mutect2
- MYBPC3 | c.2379G>A p.E793= | Silent (SNP) | VAF 66/407 reads (16%) | called by muse, mutect2, varscan2
- NKX2-5 | c.843G>A p.A281= | Silent (SNP) | VAF 90/386 reads (23%) | catalogued as COSV61298564; called by muse, varscan2
- OLIG2 | c.396C>T p.R132= | Silent (SNP) | VAF 26/444 reads (6%) | catalogued as COSV60973547; called by muse, mutect2
- PCDHGA2 | c.1743C>T p.S581= | Silent (SNP) | VAF 34/575 reads (6%) | catalogued as rs1236734969, COSV53903996, COSV99548606; called by muse, mutect2
- POLR2E | c.105G>A p.Q35= | Silent (SNP) | VAF 35/438 reads (8%) | called by muse, mutect2
- PXDNL | c.3444C>T p.H1148= | Silent (SNP) | VAF 57/375 reads (15%) | catalogued as rs201306699; called by muse, mutect2, varscan2
- PXDNL | c.2247C>T p.F749= | Silent (SNP) | VAF 32/556 reads (6%) | catalogued as rs775095055, COSV62484445; called by muse, mutect2
- RHBDF1 | c.1515C>T p.N505= | Silent (SNP) | VAF 43/527 reads (8%) | catalogued as rs568658190; called by muse, mutect2
- SEC24A | c.597T>C p.P199= | Silent (SNP) | VAF 73/292 reads (25%) | catalogued as rs991334614; called by muse, mutect2, varscan2
- SLC17A8 | c.1362C>T p.N454= | Silent (SNP) | VAF 97/407 reads (24%) | catalogued as rs185867962, COSV60123043; ClinVar: likely benign; called by muse, mutect2, varscan2
- SSC5D | c.1581G>A p.A527= | Silent (SNP) | VAF 29/593 reads (5%) | catalogued as rs1234713619; called by muse, mutect2
- TAF11L12 | c.501C>T p.P167= | Silent (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- THNSL2 | c.1314C>T p.P438= | Silent (SNP) | VAF 94/438 reads (21%) | catalogued as rs926241257, COSV100147426; called by muse, mutect2, varscan2
- TRMT11 | c.987G>T p.G329= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as rs754165136; called by muse, mutect2
- UBE3A | c.2265T>C p.I755= | Silent (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- UNC93B1 | c.1050C>T p.S350= | Silent (SNP) | VAF 30/436 reads (7%) | called by muse, mutect2
- ZNF71 | c.1311G>A p.P437= | Silent (SNP) | VAF 120/574 reads (21%) | catalogued as COSV60150794; called by muse, varscan2
- AC006213.2 | n.98del | RNA (DEL) | VAF 58/375 reads (15%) | called by mutect2, pindel, varscan2
- ZNF582 | chr19:56394380 del CTT | 5'Flank (DEL) | VAF 38/225 reads (17%) | called by mutect2, pindel, varscan2
